TARGET case TARGET-40-NAAHCG — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10e01e57-780f-558f-a0db-a4565a100d7e

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 17.6 years (6,420 days); Year of diagnosis: 2003; Metastasis at diagnosis: No Metastasis; Days to last follow up: 3,915 days (10.7 years).
   Pathology details: Necrosis percent: 40.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 1,150 days (3.1 years); Progression or recurrence: Yes; Days to progression: 1,150 days (3.1 years); Days to first event: 1,150 days (3.1 years); First event: Relapse.
- Days to follow up: 3,915 days (10.7 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2014.

Biospecimens (3 samples)
- Sample TARGET-40-NAAHCG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCG-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3915
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Histologic response: Stage 1/2 (0-90 % necrosis)
